Gene-level copy-number profile of tumor specimen HTMCP-03-06-02036-01B from CGCI case HTMCP-03-06-02036, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 54.9 years (20,064 days).
Specimen HTMCP-03-06-02036-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file baff6124-e0ed-4ae8-abb2-614fc68e6728.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02036-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b5792544-ffaa-439b-83be-88e346a3ea08

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 7,314; copy number 2: 49,795; copy number 3: 162; copy number 4: 72; copy number 5: 49; copy number 6: 997; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:106,487,364–106,544,297, 1 gene (within-gene range 0–1): CD8B2.
- chr2:111,607,841–111,612,518, 1 gene (within-gene range 0–1): AC017002.1.
- chr6:26,686,241–26,687,964, 1 gene: AL513548.1.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,047 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,565,299, 3 genes, copy number 5 (within-gene range 4–5): AC098483.1, OR2AS1P, OR2T29.
- chr3:137,723,774–198,123,232, 1,041 genes, copy number 5–6 (broad region; genes not listed).
- chr10:95,141,925–95,168,425, 1 gene, copy number 5: AL157834.4.
- chr17:20,710,425–20,710,533, 1 gene, copy number 5: AC087499.6.
- chr21:43,140,523–43,141,092, 1 gene, copy number 7: FRGCA.

Autosomal genes at a single copy (total copy number 1): 7,303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
